Somatic mutation profile of tumor specimen TCGA-EP-A2KA-01A (aliquot TCGA-EP-A2KA-01A-11D-A183-10) from TCGA case TCGA-EP-A2KA, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 52.6 years (19,214 days).
Specimen TCGA-EP-A2KA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfa4b876-fbb4-4487-879d-ff22f445a7f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EP-A2KA-10A (Blood Derived Normal), aliquot TCGA-EP-A2KA-10A-01D-A183-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85915bd7-af02-4781-9526-ee97491cd677

The open-access MAF lists 129 somatic variants for this specimen: 88 protein-altering or splice-affecting, 32 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 32, Nonsense Mutation 4, Splice Site 3, Intron 2, RNA 2, 3'UTR 2, Frame Shift Ins 2, In Frame Del 2, 5'Flank 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC2 | c.1781G>A p.S594N | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.95); PolyPhen benign (0.093); catalogued as rs777261910, COSV64986740; called by muse, mutect2, varscan2
- ADAM2 | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55863866; called by muse, mutect2
- APCS | c.199A>T p.S67C | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54818423; called by muse, mutect2
- ATAD5 | c.3200T>C p.I1067T | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs776130286, COSV58975664; called by muse, mutect2, varscan2
- CATIP | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369378162; called by muse, mutect2, varscan2
- CCR9 | c.514A>G p.I172V (on ENST00000357632 / NM_031200.3; = p.I160V on NM_006641.4) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV62939981; called by muse, mutect2, varscan2
- CCT3 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs758436442, COSV55289576; called by muse, mutect2, varscan2
- CD177 | c.72C>G p.C24W | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65121612; called by muse, mutect2, varscan2
- CFAP61 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55633717; called by muse, mutect2, varscan2
- CHD7 | c.6311C>T p.A2104V | Missense Mutation (SNP) | VAF 87/201 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.235); catalogued as COSV71112025; called by muse, mutect2, varscan2
- COQ8B | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV54687518; called by muse, mutect2, varscan2
- CRYBA1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56601029; called by muse, mutect2, varscan2
- CTNNB1 | c.553A>G p.R185G | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); catalogued as COSV62704107; called by muse, mutect2, varscan2
- CYP4B1 | c.158G>A p.W53* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as rs773563294, COSV54722556; called by muse, mutect2, varscan2
- DNAH14 | c.5488G>A p.E1830K (on ENST00000445597; = p.E2251K on NM_001367479.1) | Missense Mutation (SNP) | VAF 194/422 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs1480949066, COSV59899221; called by muse, mutect2, varscan2
- DSCAML1 | c.2408G>A p.R803H (on ENST00000321322; = p.R743H on NM_020693.4) | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); catalogued as rs1366888068, COSV58382273; called by muse, mutect2, varscan2
- DYNC1H1 | c.9236C>A p.A3079E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV64138131; called by muse, mutect2, varscan2
- EHBP1 | c.308A>C p.E103A | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV50423222; called by muse, mutect2, varscan2
- ENPP3 | c.2560A>G p.K854E | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as rs1272366803, COSV62954759; called by muse, mutect2, varscan2
- FAM161A | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 71/148 reads (48%) | SIFT tolerated (0.78); PolyPhen benign (0.445); catalogued as COSV56766673; called by muse, mutect2, varscan2
- FAT3 | c.6980T>C p.V2327A | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.501); catalogued as COSV53126425; called by muse, mutect2, varscan2
- FAT3 | c.12394T>C p.Y4132H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV53126448; called by muse, mutect2, varscan2
- FOXL1 | c.424A>G p.K142E | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV57214544; called by muse, varscan2
- GALNT17 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.981); catalogued as COSV61167416; called by muse, varscan2
- GAS2L1 | c.634-1G>T p.X212_splice | Splice Site (SNP) | VAF 64/154 reads (42%) | catalogued as COSV53330762; called by muse, mutect2, varscan2
- GAS2L1 | c.634G>T p.V212L | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53330768; called by muse, mutect2, varscan2
- GDPD3 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs761529339, COSV53774265; called by muse, mutect2, varscan2
- GLUD2 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60152156; called by muse, mutect2, varscan2
- GPBAR1 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.301); catalogued as COSV50308000; called by muse, mutect2, varscan2
- GPR68 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs969683832, COSV53176215; called by muse, mutect2, varscan2
- GRIN1 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59296842; called by muse, mutect2, varscan2
- GRIP2 | c.2623C>T p.P875S (on ENST00000619221; = p.P778S on NM_001080423.4) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV56122244; called by muse, mutect2, varscan2
- HSPA8 | c.1079A>G p.N360S | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.87); catalogued as rs756920138, COSV57084370; called by muse, mutect2
- HTT | c.7756G>T p.A2586S | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV61863925; called by muse, mutect2, varscan2
- ICMT | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 40/165 reads (24%) | catalogued as COSV59473833; called by muse, mutect2, varscan2
- IGDCC3 | c.2206-1G>T p.X736_splice | Splice Site (SNP) | VAF 14/41 reads (34%) | catalogued as COSV60078162; called by muse, mutect2, varscan2
- IL1R1 | c.1142A>G p.D381G | Missense Mutation (SNP) | VAF 105/524 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761337171, COSV52106557, COSV99292844; called by muse, mutect2, varscan2
- KCNA10 | c.368A>G p.D123G | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63904804; called by muse, varscan2
- KCNA5 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52906284; called by muse, mutect2, varscan2
- KDM6B | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.948); catalogued as rs755801518, COSV54682865; called by muse, mutect2, varscan2
- KMT2B | c.7872+1G>T p.X2624_splice | Splice Site (SNP) | VAF 15/43 reads (35%) | catalogued as COSV53075427; called by muse, mutect2, varscan2
- KRTAP10-7 | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 117/356 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as rs1555928561, COSV59110908; called by muse, mutect2, varscan2
- LRP1 | c.5024C>G p.T1675R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54514934; called by muse, mutect2, varscan2
- LRP1B | c.2011G>T p.D671Y | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV67234699; called by muse, mutect2, varscan2
- LRP2 | c.9206A>T p.H3069L | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.062); catalogued as COSV55558392; called by muse, mutect2, varscan2
- LUZP2 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV61200340, COSV61208039; called by muse, mutect2, varscan2
- MBD1 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.174); catalogued as COSV54002989, COSV54003048; called by muse, mutect2, varscan2
- MGAT1 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 26/84 reads (31%) | PolyPhen probably damaging (0.991); catalogued as COSV100286509, COSV57134428; called by muse, mutect2, varscan2
- MRPS5 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs768319910, COSV55534148, COSV55534976; called by muse, mutect2, varscan2
- MS4A13 | c.232A>T p.I78F | Missense Mutation (SNP) | VAF 115/332 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV65445770; called by muse, mutect2, varscan2
- NBEA | c.8323G>A p.V2775I | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs368581341; called by muse, mutect2, varscan2
- NCOA3 | c.1439T>G p.I480S | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV59069824; called by muse, mutect2, varscan2
- NCOA3 | c.2194_2196del p.K732del | In Frame Del (DEL) | VAF 38/194 reads (20%) | catalogued as rs1475395274; called by pindel, varscan2
- NSD1 | c.7867A>C p.S2623R | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.048); catalogued as COSV61778021; called by muse, mutect2, varscan2
- NTRK2 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs997635600, COSV52856453; called by muse, mutect2, varscan2
- NYAP2 | c.506C>T p.T169I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1274355128, COSV56008094; called by muse, mutect2, varscan2
- NYAP2 | c.923A>G p.K308R | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as COSV56008103; called by muse, mutect2, varscan2
- OR10G8 | c.883A>T p.K295* | Nonsense Mutation (SNP) | VAF 56/186 reads (30%) | catalogued as COSV70908700; called by muse, mutect2, varscan2
- OR8G5 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.033); catalogued as COSV58381582; called by muse, mutect2, varscan2
- PGD | c.592A>T p.I198F | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54621901; called by muse, mutect2, varscan2
- PGM5 | c.1678C>G p.R560G | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV67168133; called by muse, mutect2, varscan2
- PLXNB3 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV62798370; called by muse, mutect2, varscan2
- PPFIA3 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV61952492; called by muse, mutect2, varscan2
- PRAMEF19 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 248/1179 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs751509729, COSV65820773; called by muse, mutect2, varscan2
- PREX2 | c.4495G>A p.A1499T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV55777929; called by muse, mutect2, varscan2
- PROM2 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs553459907, COSV58296835; called by muse, mutect2, varscan2
- PTPRS | c.4079C>T p.P1360L | Missense Mutation (SNP) | VAF 65/337 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.029); catalogued as rs753417682, COSV53623632; called by muse, mutect2, varscan2
- RYR3 | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66795030; called by muse, mutect2, varscan2
- SECISBP2L | c.758C>G p.P253R | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV55935176; called by muse, mutect2, varscan2
- SH3D19 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.445); catalogued as COSV58791252; called by muse, mutect2, varscan2
- SLC26A6 | c.526A>T p.R176* | Nonsense Mutation (SNP) | VAF 101/239 reads (42%) | catalogued as COSV50887090; called by muse, mutect2, varscan2
- SLITRK2 | c.2107C>A p.Q703K | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.351); catalogued as COSV59426400; called by muse, mutect2, varscan2
- SPATA16 | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 180/1140 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.069); catalogued as COSV63530270; called by muse, mutect2, varscan2
- SPECC1 | c.299C>G p.T100S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV54959953; called by muse, mutect2, varscan2
- TET2 | c.506A>T p.H169L | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV54416327; called by muse, mutect2, varscan2
- TOM1L2 | c.164A>G p.K55R | Missense Mutation (SNP) | VAF 110/268 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.214); catalogued as COSV58886693; called by muse, mutect2, varscan2
- TRIM59 | c.1018G>C p.V340L | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV59087531; called by muse, mutect2, varscan2
- TRIM66 | c.3047G>A p.S1016N | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.147); catalogued as COSV55126681; called by muse, mutect2, varscan2
- TSC1 | c.2166G>T p.K722N | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV53768299; called by muse, mutect2, varscan2
- UBR4 | c.15179G>A p.R5060Q | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs372882903; called by muse, mutect2, varscan2
- WFIKKN2 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs761597315, COSV100260125, COSV60959159; called by muse, mutect2, varscan2
- XPO6 | c.1055A>T p.N352I | Missense Mutation (SNP) | VAF 159/493 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV58967686; called by muse, mutect2, varscan2
- ZNF354C | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV59608659; called by muse, mutect2
- ZNF75A | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV73039636; called by muse, mutect2, varscan2
- BACE1 | c.969dup p.L324Afs*28 | Frame Shift Ins (INS) | VAF 19/70 reads (27%) | called by mutect2, pindel, varscan2
- KMT5A | c.535_543del p.R179_L181del | In Frame Del (DEL) | VAF 30/67 reads (45%) | called by mutect2, pindel, varscan2
- SMARCC2 | c.3561_3562dup p.L1188Hfs*96 | Frame Shift Ins (INS) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- WDR7 | c.352del p.Q118Sfs*35 | Frame Shift Del (DEL) | VAF 39/160 reads (24%) | called by mutect2, pindel, varscan2
- ABCA3 | c.2667G>A p.E889= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV57055252; called by muse, mutect2, varscan2
- BOC | c.519C>T p.S173= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV56352869; called by muse, mutect2, varscan2
- CBX7 | c.555G>A p.A185= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs765884458, COSV53358864; called by muse, mutect2, varscan2
- CCDC22 | c.1368G>T p.L456= | Silent (SNP) | VAF 35/158 reads (22%) | catalogued as COSV66051527; called by muse, mutect2, varscan2
- CCPG1 | c.612G>A p.K204= | Silent (SNP) | VAF 32/186 reads (17%) | catalogued as COSV60525964; called by muse, mutect2, varscan2
- CD300LG | c.36G>A p.L12= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV53224326; called by muse, mutect2, varscan2
- CD48 | c.702G>A p.V234= | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as COSV63566896; called by muse, mutect2, varscan2
- DIRAS3 | c.117C>T p.R39= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as rs1359297766, COSV63970826; called by muse, mutect2, varscan2
- DMD | c.2922C>A p.I974= | Silent (SNP) | VAF 39/140 reads (28%) | catalogued as COSV63764477, COSV63765879; called by muse, mutect2, varscan2
- EIF2A | c.660G>A p.K220= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs958986245, COSV56407277; called by muse, mutect2, varscan2
- ETF1 | c.1308C>T p.D436= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as COSV62127578; called by muse, mutect2, varscan2
- EVX2 | c.249C>T p.G83= | Silent (SNP) | VAF 48/240 reads (20%) | catalogued as COSV100420643, COSV57963820; called by muse, mutect2, varscan2
- FKBP5 | c.159T>G p.V53= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV61882099; called by muse, mutect2, varscan2
- FOXR1 | c.42C>A p.L14= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs145283417; called by muse, mutect2, varscan2
- GABRA1 | c.334C>A p.R112= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as COSV50107944; called by muse, mutect2, varscan2
- GPSM1 | c.1665C>T p.I555= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs781889669, COSV52517768; called by muse, mutect2, varscan2
- KCNQ3 | c.1272G>A p.L424= | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as COSV66473200; called by muse, mutect2, varscan2
- KIAA1549 | c.4653C>T p.D1551= | Silent (SNP) | VAF 27/176 reads (15%) | catalogued as rs575482000, COSV54317476; called by muse, mutect2, varscan2
- KLC2 | c.990G>T p.L330= | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as COSV57583088; called by muse, mutect2, varscan2
- LRP4 | c.4137C>A p.V1379= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV66136449; called by muse, mutect2, varscan2
- OR4K14 | c.120G>T p.L40= | Silent (SNP) | VAF 71/209 reads (34%) | catalogued as COSV59293123, COSV59294513; called by muse, mutect2, varscan2
- PHKA1 | c.375G>A p.V125= | Silent (SNP) | VAF 166/631 reads (26%) | catalogued as rs1569452033, COSV59807226; called by muse, mutect2, varscan2
- PHLDB2 | c.1273C>T p.L425= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV67312555; called by muse, mutect2, varscan2
- PLXNB2 | c.3039G>A p.R1013= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV63782466; called by muse, mutect2, varscan2
- SAA2-SAA4 | c.540G>T p.S180= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as COSV53447766, COSV53448439; called by muse, mutect2, varscan2
- SLC16A5 | c.1293G>C p.A431= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as COSV61676164; called by muse, mutect2, varscan2
- SNX12 | c.258C>T p.S86= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV52145886; called by muse, mutect2, varscan2
- TCIRG1 | c.2328C>A p.I776= | Silent (SNP) | VAF 150/355 reads (42%) | catalogued as COSV55835427, COSV55836223; called by muse, mutect2, varscan2
- TMEM30A | c.501A>G p.P167= | Silent (SNP) | VAF 64/175 reads (37%) | catalogued as COSV57875642; called by muse, mutect2, varscan2
- TNXB | c.5817C>A p.L1939= (on ENST00000647633; = p.L1692= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as COSV64480948; called by muse, mutect2, varscan2
- ZNF585B | c.1332G>A p.G444= | Silent (SNP) | VAF 58/186 reads (31%) | catalogued as COSV57215973; called by muse, mutect2, varscan2
- ZNF839 | c.1345C>A p.R449= (on ENST00000558850 / NM_001267827.1; = p.R565= on NM_018335.5) | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as rs535523717, COSV51757900, COSV99216274; called by muse, mutect2, varscan2
- C11orf87 | c.*1354T>C | 3'UTR (SNP) | VAF 28/92 reads (30%) | catalogued as rs561719013, COSV100535781; called by muse, mutect2, varscan2
- C3P1 | n.2385A>G | RNA (SNP) | VAF 43/192 reads (22%) | called by muse, mutect2, varscan2
- FBXO46 | c.-41A>C | 5'UTR (SNP) | VAF 39/141 reads (28%) | catalogued as COSV100480171; called by muse, mutect2, varscan2
- FCRL5 | c.1681+74dup | Intron (INS) | VAF 30/328 reads (9%) | called by mutect2, pindel
- KCNJ12 | chr17:21417406 G>A | 3'Flank (SNP) | VAF 36/92 reads (39%) | catalogued as COSV100054777; called by muse, varscan2
- STX11 | c.*1940C>G | 3'UTR (SNP) | VAF 109/448 reads (24%) | called by muse, mutect2, varscan2
- TMEM255B | c.190-834C>T | Intron (SNP) | VAF 34/114 reads (30%) | catalogued as rs748037444; called by muse, mutect2, varscan2
- TMPRSS11BNL | n.276C>A | RNA (SNP) | VAF 81/282 reads (29%) | called by muse, mutect2, varscan2
- ZSWIM2 | chr2:186849176 G>A | 5'Flank (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
